Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A05H, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A05H-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

adenocarcinoma, serous, NOS 8441/3
Site: endometrium C54.1 w 5/2/11

Specimens Submitted:

- 1: Uterus, cervix, fallopian tubes and ovaries; Total hysterectomy with bilateral salpingo-oophorectomy
- 2: Lymph nodes, para-aortic, Right; Excision
- 3: Lymph nodes, common iliac, Right; Excision
- 4: Lymph nodes, Presacral; Excision
- 5: Lymph nodes, para-aortic, Left; Excision
- 6: Omentum; Partial omentectomy
- 7: Pelvic wall, Right; Biopsy
- 8: Lymph nodes, external iliac, Right; Excision
- 9: Lymph nodes, obturator, Right; Excision
- 10: Lymph nodes, external iliac, Left; Excision
- 11: Lymph nodes, obturator, Left; Excision
- 12: Lymph nodes, common iliac, Left; Excision
- 13: Cul-de-sac, Anterior; Biopsy
- 14: Cul-de-sac, Posterior; Biopsy
- 15: Pelvic wall, Left; Biopsy
- 16: Paracolic gutter, Right; Biopsy
- 17: Diaphragm, Right; Biopsy
- 18: paracolic, Left; Biopsy
- 19: Diaphragm, Left; Biopsy

DIAGNOSIS:

1. Uterus, cervix, fallopian tubes and ovaries; Total hysterectomy with bilateral salpingo-oophorectomy:

Tumor Type:

Endometrial adenocarcinoma, serous type

Myometrial Invasion:

(>50%)

Measures 11mm in maximum depth

Myometrium thickness measures 18mm in the area of maximal tumor

invasion

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Not identified

Endometrium:

** Continued on next page **

[page 2 of 3]
Exhibits atrophy

Myometrium:

Exhibits one leiomyoma

Adnexa:

Unremarkable

2. Lymph nodes, para-aortic, Right; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:3

3. Lymph nodes, common iliac, Right; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:3

4. Lymph nodes, Presacral; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:1

5. Lymph nodes, para-aortic, Left; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:4

6. Omentum; Partial omentectomy :

- Benign fibroadipose tissue.

7. Pelvic wall, Right; Biopsy :

- Benign fibrovascular tissue.

8. Lymph nodes, external iliac, Right; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:4

9. Lymph nodes, obturator, Right; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:4

** Continued on next page **

[page 3 of 3]
10. Lymph nodes, external iliac, Left; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:5

11. Lymph nodes, obturator, Left; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:6

12. Lymph nodes, common iliac, Left; Excision:

Lymph Nodes:

Not involved

Number of nodes examined:1

13. Cul-de-sac, Anterior; Biopsy :

- Benign fibroadipose tissue.

14. Cul-de-sac, Posterior; Biopsy :

- Benign fibroadipose tissue.

15. Pelvic wall, Left; Biopsy :

- Benign fibroadipose tissue.

16. Paracolic gutter, Right; Biopsy :

- Benign fibroadipose tissue.

17. Diaphragm, Right; Biopsy :

- Benign fibroadipose tissue.

18. Paracolic, Left; Biopsy :

- Benign fibromuscular tissue.

19. Diaphragm, Left; Biopsy :

- Benign fibromuscular tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file b2aeadd2-f6f6-4722-9f98-fe9433e4d6fe (TCGA-AP-A05H.805B997D-9755-4AC1-8695-294806148F25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).